CPTAC case C3L-06193 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/91d5692b-ecb6-4a79-b450-04985dd1f4c6

Demographics
Sex at birth: male; Race: white; Year of birth: 1973; Vital status: Alive; Country of birth: Serbia.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 47.8 years (17,472 days); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T4b; AJCC pathologic N: N3; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIID; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,447 days (4.0 years); Progression or recurrence: no; Days to last follow up: 1,447 days (4.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 7 cm; Lymph node involvement: Positive; Lymph nodes positive: 13; Lymph nodes tested: 19; Margin status: Indeterminate.

Follow-up (3 entries)
- Days to follow up: 334 days; Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 775 days (2.1 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,076 days (2.9 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-06193-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 21 days; Initial weight: 435 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-06193-25: Section location: Lymph node; Percent tumor nuclei: 85; Percent necrosis: 7.
- Sample C3L-06193-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 21 days; Method of sample procurement: Blood Draw.
